Somatic mutation profile of tumor specimen TCGA-HF-7134-01A (aliquot TCGA-HF-7134-01A-11D-2053-08) from TCGA case TCGA-HF-7134, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IA; Tumor grade: G2.
Specimen TCGA-HF-7134-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f956875-dfd7-44b2-ad8b-4bbcbf48ef48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HF-7134-10A (Blood Derived Normal), aliquot TCGA-HF-7134-10A-01D-2053-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a165aa2d-e890-4f3c-b16a-e85f617e33d2

The open-access MAF lists 299 somatic variants for this specimen: 225 protein-altering or splice-affecting, 70 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 203, Silent 70, Nonsense Mutation 11, Splice Site 7, Frame Shift Del 2, RNA 2, Splice Region 1, Intron 1, Frame Shift Ins 1, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 17/35 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ERBB4 | c.3005A>C p.K1002T | Missense Mutation (SNP) | VAF 22/58 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV61479977, COSV61490260; called by muse, mutect2, varscan2
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 17/59 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.3514G>A p.G1172S | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs751595372, COSV100932992; called by muse, mutect2, varscan2
- ABCC9 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs374849789; called by muse, mutect2, varscan2
- ADAMTS18 | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV99270737; called by muse, mutect2, varscan2
- ADAMTS5 | c.1302A>C p.E434D | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.062); catalogued as COSV99536770; called by muse, mutect2, varscan2
- ADGRL3 | c.2186A>C p.D729A (on ENST00000506720 / NM_001322402.2; = p.D661A on NM_015236.6) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV101546712, COSV72231707; called by muse, mutect2, varscan2
- ADGRL4 | c.1323T>G p.C441W | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100875472; called by muse, mutect2, varscan2
- AGO1 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.87); PolyPhen benign (0.03); catalogued as rs1203451050, COSV100940722; called by muse, mutect2, varscan2
- AHSP | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs555330651, COSV56529210; called by muse, mutect2, varscan2
- AKAP8L | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV101275689; called by muse, varscan2
- ALPK1 | c.2870C>T p.S957F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51584459, COSV99452703; called by muse, mutect2, varscan2
- AMER3 | c.509A>C p.K170T | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749142142, COSV100365818; called by muse, mutect2, varscan2
- ANKH | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.27); catalogued as rs986240035, COSV99414360; called by muse, mutect2, varscan2
- ANKRD20A2P | c.2426G>C p.S809T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.98); PolyPhen benign (0.18); catalogued as rs966522466; called by mutect2, varscan2
- APIP | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99551307; called by muse, mutect2, varscan2
- ARL5A | c.151A>G p.N51D | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99706507; called by muse, mutect2, varscan2
- ART3 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.9); catalogued as COSV100587410; called by muse, mutect2, varscan2
- ASIC5 | c.440A>C p.N147T | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.105); catalogued as COSV101539702; called by muse, mutect2, varscan2
- AWAT2 | c.898G>C p.V300L | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99339491, COSV99339697; called by muse, mutect2, varscan2
- B3GAT2 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.325); catalogued as rs757375740, COSV57770191; called by muse, mutect2, varscan2
- BANF1 | c.32T>C p.V11A | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV100381316; called by muse, mutect2, varscan2
- BANK1 | c.920T>G p.L307R | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100535569; called by muse, mutect2, varscan2
- BICC1 | c.2641C>A p.L881I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99570025; called by muse, mutect2, varscan2
- BRINP2 | c.1325G>T p.S442I | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV100837774; called by muse, mutect2, varscan2
- BRINP2 | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs201898561, COSV64176183; called by muse, mutect2, varscan2
- C12orf71 | c.248T>G p.F83C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV101460493; called by muse, mutect2, varscan2
- C7orf31 | c.1487C>T p.T496M | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs147311660; called by muse, mutect2
- CACNA2D1 | c.2054A>G p.E685G (on ENST00000356253 / NM_001366867.1; = p.E673G on NM_000722.4) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV100665108; called by muse, mutect2, varscan2
- CACNA2D1 | c.1036A>C p.N346H | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100665111; called by muse, mutect2, varscan2
- CARD11 | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs1322611135, COSV101210354; called by muse, mutect2, varscan2
- CASR | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.057); catalogued as rs868784672, COSV99948306; called by muse, mutect2, varscan2
- CBFA2T3 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs147184929; called by muse, mutect2, varscan2
- CBLN4 | c.415T>G p.L139V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99290259; called by muse, mutect2, varscan2
- CCDC91 | c.1038A>C p.K346N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV100080913; called by muse, mutect2, varscan2
- CD36 | c.1181A>G p.K394R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as rs778081291, COSV99987032; called by muse, mutect2, varscan2
- CDH23 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs371422466, CM1512993; ClinVar: likely benign; called by muse, mutect2, varscan2
- CEP290 | c.5260G>A p.E1754K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58358794; called by muse, mutect2, varscan2
- CFAP251 | c.1048A>G p.M350V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs747183230, COSV99995568; called by muse, mutect2, varscan2
- CFAP65 | c.3295G>A p.V1099I | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as rs145571723; called by muse, mutect2, varscan2
- CLDN5 | c.49G>A p.G17S (on ENST00000618236 / NM_001363066.2; = p.G102S on NM_003277.4) | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99596328; called by muse, mutect2, varscan2
- CNTLN | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99262184; called by muse, mutect2, varscan2
- COG2 | c.701A>C p.Y234S | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100794544, COSV64186570; called by muse, mutect2, varscan2
- COG2 | c.702C>A p.Y234* | Nonsense Mutation (SNP) | VAF 41/77 reads (53%) | catalogued as COSV100794545; called by muse, mutect2, varscan2
- COL24A1 | c.3652A>G p.R1218G | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100992756; called by muse, mutect2, varscan2
- CRY2 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.06); catalogued as COSV101314539; called by muse, mutect2, varscan2
- CSF3R | c.1431G>A p.W477* | Nonsense Mutation (SNP) | VAF 59/154 reads (38%) | catalogued as COSV100117111; called by muse, mutect2, varscan2
- CSMD2 | c.6193A>T p.N2065Y | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99583903; called by muse, mutect2, varscan2
- CTNNA3 | c.972C>G p.H324Q | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV101044321; called by muse, mutect2, varscan2
- CXorf38 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1419221605, COSV100010145; called by muse, mutect2, varscan2
- CYP1A1 | c.1043-1G>T p.X348_splice | Splice Site (SNP) | VAF 19/42 reads (45%) | catalogued as COSV101122188; called by muse, mutect2, varscan2
- DCST1 | c.1612+1G>A p.X538_splice | Splice Site (SNP) | VAF 19/129 reads (15%) | catalogued as rs147139841; called by muse, mutect2, varscan2
- DDX27 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 106/366 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100874627; called by muse, mutect2, varscan2
- DGKD | c.2830G>C p.A944P (on ENST00000264057 / NM_152879.3; = p.A900P on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV51062617, COSV99894885; called by muse, mutect2, varscan2
- DLG2 | c.181C>A p.L61I (on ENST00000650630 / NM_001351274.2; = p.L24I on NM_001142699.3) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV101069640; called by muse, mutect2, varscan2
- DOCK4 | c.181T>G p.Y61D | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101455408; called by muse, mutect2, varscan2
- DPYSL3 | c.1042T>G p.F348V | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100574850; called by muse, mutect2, varscan2
- EDNRB | c.937G>T p.V313F (on ENST00000377211 / NM_001201397.1; = p.V223F on NM_000115.5) | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs751199972, COSV100526039; called by muse, mutect2, varscan2
- EPPIN | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335648940, COSV100323040; called by muse, mutect2, varscan2
- EYA4 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.22); catalogued as rs764985361, COSV62051540; called by muse, mutect2, varscan2
- FAM131C | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs373773381; called by muse, mutect2, varscan2
- FDPS | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 77/383 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs1266955055, COSV99429308; called by muse, mutect2, varscan2
- FLG | c.2671A>C p.S891R | Missense Mutation (SNP) | VAF 552/890 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1476265194, COSV100910462, COSV64239905; called by muse, mutect2, varscan2
- FMOD | c.1096C>G p.L366V | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.679); catalogued as COSV100724454; called by muse, mutect2, varscan2
- FOXP1 | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100560501; called by muse, mutect2, varscan2
- FRY | c.3873C>A p.Y1291* | Nonsense Mutation (SNP) | VAF 24/96 reads (25%) | catalogued as COSV100968641; called by muse, mutect2, varscan2
- GABRA1 | c.1042A>C p.S348R | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV50099571, COSV99195668; called by muse, mutect2, varscan2
- GFRA2 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.619); catalogued as rs201199040; called by muse, mutect2, varscan2
- GLIS3 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV100172996; called by muse, mutect2, varscan2
- GML | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 69/135 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV55276720; called by muse, mutect2, varscan2
- GOLGA3 | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748744472, COSV52626115; called by muse, mutect2, varscan2
- GPR119 | c.893A>C p.K298T | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99358509; called by muse, mutect2, varscan2
- GPR12 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1245945449, COSV67344549; called by muse, mutect2, varscan2
- GRM4 | c.2468C>T p.T823M | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1000580962, COSV100945563; called by muse, mutect2, varscan2
- GRM7 | c.2687T>C p.V896A | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1042449830, COSV100735079; called by muse, mutect2, varscan2
- GTPBP1 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.647); catalogued as rs765222657, COSV53288283; called by muse, mutect2, varscan2
- HACE1 | c.2309C>G p.P770R | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.564); catalogued as COSV53507884, COSV99493132; called by muse, mutect2
- HIVEP1 | c.4696G>T p.V1566F | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.807); catalogued as COSV101044358; called by muse, mutect2, varscan2
- HNRNPL | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1319143014, COSV99669824; called by muse, mutect2, varscan2
- HSPA4L | c.661A>C p.K221Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99612312; called by muse, mutect2, varscan2
- HTR1A | c.701A>G p.E234G | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV100108790; called by muse, mutect2, varscan2
- IGHM | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.08); catalogued as rs1555378355; called by muse, mutect2, varscan2
- IGHV3-23 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 103/415 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.132); catalogued as rs782086688; called by muse, mutect2, varscan2
- IGSF9 | c.2327-1G>A p.X776_splice (on ENST00000368094 / NM_001135050.2; = p.X760_splice on NM_020789.4) | Splice Site (SNP) | VAF 29/114 reads (25%) | catalogued as rs1202495640, COSV100230905; called by muse, mutect2, varscan2
- IL20RB | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV100290891, COSV100291102; called by muse, mutect2, varscan2
- IMPG2 | c.3138A>C p.E1046D | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51975627; called by muse, mutect2, varscan2
- IMPG2 | c.3044A>G p.K1015R | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1220285957, COSV51981407, COSV51981974, COSV51983300; called by muse, mutect2, varscan2
- IQSEC2 | c.1973C>T p.P658L (on ENST00000642864 / NM_001111125.3; = p.P453L on NM_015075.2) | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV100944664; called by muse, mutect2, varscan2
- ITGBL1 | c.610A>C p.N204H | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.986); catalogued as COSV101094886; called by muse, mutect2, varscan2
- JHY | c.1163A>G p.Q388R | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as rs1318011355, COSV99912413; called by muse, mutect2, varscan2
- KATNAL2 | c.251A>G p.Q84R (on ENST00000356157 / NM_001353899.1; = p.Q12R on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.635); catalogued as rs1457723551, COSV99795620; called by muse, mutect2, varscan2
- KCNE3 | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100035481; called by muse, mutect2, varscan2
- KCNN2 | c.454G>A p.E152K (on ENST00000264773; = p.E364K on NM_021614.4) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99298431; called by muse, mutect2, varscan2
- KDR | c.1477G>T p.G493* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV55767810, COSV55779634; called by muse, mutect2, varscan2
- KDR | c.1476G>T p.Q492H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV99816327; called by muse, mutect2, varscan2
- KDR | c.950A>C p.K317T | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV99816332; called by muse, varscan2
- KIF3C | c.2002G>T p.G668C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.774); catalogued as rs370777128; called by muse, mutect2, varscan2
- KIRREL2 | c.419T>G p.V140G | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.378); catalogued as COSV99383390; called by muse, mutect2, varscan2
- KLHDC7A | c.2276C>A p.T759N | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.443); catalogued as COSV101272686, COSV68769640; called by muse, mutect2, varscan2
- KNG1 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.05); catalogued as rs1402537213, COSV99404906; called by muse, mutect2, varscan2
- LAMA4 | c.4345C>T p.R1449W (on ENST00000230538 / NM_001105206.3; = p.R1442W on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs372872387, COSV100037325; called by muse, mutect2, varscan2
- LAMC3 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 39/47 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as rs144206115; called by muse, mutect2, varscan2
- LHFPL4 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV99804904; called by muse, mutect2, varscan2
- LRP12 | c.1154A>C p.N385T | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV52626891; called by muse, mutect2, varscan2
- LRP1B | c.3964+1G>A p.X1322_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as COSV101249245; called by muse, varscan2
- LYZL4 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779626788, COSV99821087; called by muse, mutect2, varscan2
- MAGEE1 | c.1652T>G p.L551R | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100819199, COSV63910080, COSV63912447; called by muse, mutect2, varscan2
- MAP2 | c.1046A>G p.D349G | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.097); catalogued as COSV99556994; called by muse, mutect2, varscan2
- MAP2K7 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101209051, COSV67609125; called by muse, mutect2, varscan2
- MBOAT1 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100208224; called by muse, mutect2, varscan2
- MBOAT1 | c.925G>T p.A309S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61123863, COSV61128051; called by muse, mutect2, varscan2
- MCAM | c.246G>C p.Q82H | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.852); catalogued as COSV99877460; called by muse, mutect2, varscan2
- MEI1 | c.1177T>A p.F393I | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV100299370; called by muse, mutect2, varscan2
- METAP1D | c.705-1G>A p.X235_splice | Splice Site (SNP) | VAF 12/34 reads (35%) | catalogued as rs530856668, COSV100249707; called by muse, mutect2, varscan2
- MROH7 | c.3189C>A p.H1063Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV100272646; called by muse, mutect2, varscan2
- MSR1 | c.1033A>C p.T345P (on ENST00000262101 / NM_138715.3; = p.R345= on NM_002445.4) | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs536722892, COSV100026208, COSV100026960; called by muse, mutect2, varscan2
- MYH3 | c.1529C>T p.T510M | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.667); catalogued as rs1182023838, COSV56865459; called by muse, mutect2, varscan2
- MYH7 | c.5095C>T p.R1699W | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1297199116, COSV100805522; called by muse, mutect2, varscan2
- MYH7 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs730880828, COSV100806177, COSV62517999; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYL1 | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761037368, COSV100498587; called by muse, mutect2, varscan2
- MYO5C | c.2255G>A p.R752Q | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1331159911, COSV55912845; called by muse, mutect2, varscan2
- NALCN | c.21T>G p.S7R | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99212633; called by muse, mutect2, varscan2
- NBEA | c.4965A>T p.K1655N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.056); catalogued as COSV100075386; called by muse, mutect2, varscan2
- NCKAP5 | c.3578C>T p.S1193F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.804); catalogued as COSV100489204; called by muse, mutect2, varscan2
- NEBL | c.2890G>T p.D964Y | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101009015, COSV65802861; called by muse, mutect2, varscan2
- NLRP13 | c.178T>A p.L60M | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.579); catalogued as COSV100737900, COSV100738454, COSV61623520; called by muse, mutect2, varscan2
- NME4 | c.333G>A p.W111* | Nonsense Mutation (SNP) | VAF 41/145 reads (28%) | catalogued as COSV99556658; called by muse, mutect2, varscan2
- OLIG3 | c.32G>T p.R11I | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100880191; called by muse, mutect2, varscan2
- OLR1 | c.568T>G p.F190V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100376257; called by muse, mutect2, varscan2
- OPN1LW | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 72/98 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as rs1398682615, COSV100886830; called by muse, mutect2, varscan2
- OR10J3 | c.115A>C p.T39P | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV100171535; called by muse, mutect2, varscan2
- OR10X1 | c.652A>C p.I218L | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.113); catalogued as COSV100936556; called by muse, mutect2, varscan2
- OR11H1 | c.776T>A p.L259H | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99421475; called by mutect2, varscan2
- OR13H1 | c.499T>G p.F167V | Missense Mutation (SNP) | VAF 135/171 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100088078; called by muse, mutect2, varscan2
- OR2D2 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs113796560, COSV55057117; called by muse, mutect2, varscan2
- OR2T4 | c.518G>C p.C173S | Missense Mutation (SNP) | VAF 93/452 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV100822380; called by muse, varscan2
- OR51G1 | c.434A>G p.K145R | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs774270415, COSV100429072, COSV58970054; called by muse, mutect2, varscan2
- OR52I2 | c.912A>C p.Q304H | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); catalogued as COSV57044069, COSV57044562; called by muse, mutect2, varscan2
- OR5AS1 | c.29C>A p.T10N | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs775788693, COSV100546118; called by muse, mutect2, varscan2
- OR5AS1 | c.310T>G p.F104V | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57982049; called by muse, mutect2, varscan2
- OR5B12 | c.175T>G p.F59V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV100222282; called by muse, mutect2, varscan2
- OR5T2 | c.427G>C p.A143P | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV100506718; called by muse, mutect2, varscan2
- P3H1 | c.1081-1G>A p.X361_splice | Splice Site (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99354666; called by muse, mutect2, varscan2
- PABPC3 | c.89A>C p.K30T | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as COSV99878822; called by muse, mutect2, varscan2
- PABPC4 | c.322A>T p.K108* | Nonsense Mutation (SNP) | VAF 28/60 reads (47%) | catalogued as COSV100790826; called by muse, mutect2, varscan2
- PAG1 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs757186553, COSV55058476; called by muse, mutect2, varscan2
- PCDHB12 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.171); catalogued as rs782027801, COSV53400379; called by muse, mutect2, varscan2
- PCDHB6 | c.747A>C p.Q249H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV99169859; called by muse, mutect2, varscan2
- PCDHB6 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as rs750545117, COSV50689702; called by muse, mutect2, varscan2
- PCF11 | c.2977A>G p.I993V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100017611; called by muse, mutect2, varscan2
- PCSK7 | c.1838A>C p.Y613S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99638863; called by mutect2, varscan2
- PIGC | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs376403107; called by muse, mutect2, varscan2
- PLEKHH2 | c.4296G>A p.K1432= | Splice Region (SNP) | VAF 15/53 reads (28%) | catalogued as rs370169278; called by muse, mutect2, varscan2
- POU3F3 | c.1394C>T p.T465M | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100796824; called by muse, mutect2, varscan2
- PRAMEF4 | c.473A>C p.K158T | Missense Mutation (SNP) | VAF 46/255 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.798); catalogued as COSV99339301; called by muse, mutect2, varscan2
- PYGB | c.2408T>C p.I803T | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99404726; called by muse, mutect2, varscan2
- PZP | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs1484707847, COSV99735389; called by muse, mutect2, varscan2
- R3HDML | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1272661605, COSV99406953; called by muse, mutect2, varscan2
- RARB | c.279C>A p.D93E (on ENST00000383772 / NM_001290216.2; = p.D86E on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100412005, COSV58070413; called by muse, mutect2, varscan2
- RELT | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99292594; called by muse, mutect2, varscan2
- RNF165 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV99491134; called by muse, mutect2, varscan2
- ROBO1 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101458219, COSV71394365; called by muse, mutect2, varscan2
- SCN2A | c.2350A>G p.T784A | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV99329485; called by muse, mutect2, varscan2
- SCN2A | c.5426C>A p.A1809E | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51836417, COSV99329489; called by muse, mutect2, varscan2
- SCN8A | c.3172G>A p.D1058N | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as COSV100632936; called by muse, mutect2, varscan2
- SERPINA7 | c.971G>A p.G324D | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59666478; called by muse, mutect2, varscan2
- SETBP1 | c.2981A>G p.Y994C | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99951470; called by muse, mutect2, varscan2
- SETD2 | c.3167C>T p.S1056L | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); catalogued as rs776300341, COSV100337680; called by muse, mutect2, varscan2
- SHANK2 | c.2906G>A p.R969Q | Missense Mutation (SNP) | VAF 64/408 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.519); catalogued as rs782396100, COSV53617108; called by muse, mutect2, varscan2
- SLAMF8 | c.468C>A p.N156K | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV99222608; called by muse, mutect2, varscan2
- SLC24A5 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165007; called by muse, varscan2
- SLC39A12 | c.1378T>G p.L460V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.857); catalogued as COSV101069749; called by muse, mutect2, varscan2
- SLITRK6 | c.2238T>G p.F746L | Missense Mutation (SNP) | VAF 123/208 reads (59%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV101233154; called by muse, mutect2, varscan2
- SMO | c.1037T>G p.L346R | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99976088; called by muse, mutect2, varscan2
- SPOCK3 | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 86/276 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100691293, COSV62717079; called by muse, mutect2, varscan2
- SPTA1 | c.7124A>T p.D2375V | Missense Mutation (SNP) | VAF 94/153 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs748453976, COSV100933967, COSV100934073; called by muse, mutect2, varscan2
- SPTA1 | c.7123G>A p.D2375N | Missense Mutation (SNP) | VAF 94/153 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV100933968; called by muse, mutect2, varscan2
- SPTA1 | c.2010G>T p.E670D | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100933969; called by mutect2, varscan2
- ST18 | c.753T>G p.D251E | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.551); catalogued as COSV99387558; called by muse, mutect2, varscan2
- STK19 | c.347A>G p.H116R | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100514485; called by muse, mutect2, varscan2
- STXBP5L | c.1351G>A p.G451R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56506676; called by muse, mutect2, varscan2
- SUN1 | c.1406A>C p.E469A (on ENST00000405266 / NM_001367651.1; = p.E349A on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as COSV100568409; called by muse, mutect2, varscan2
- SYNE1 | c.21518T>G p.L7173R (on ENST00000367255 / NM_182961.4; = p.L7102R on NM_033071.3) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99548860; called by muse, mutect2, varscan2
- SYNE1 | c.20199+2T>G p.X6733_splice (on ENST00000367255 / NM_182961.4; = p.X6662_splice on NM_033071.3) | Splice Site (SNP) | VAF 29/104 reads (28%) | catalogued as COSV99548865; called by muse, mutect2, varscan2
- TAS2R1 | c.585G>T p.L195F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs771063946, COSV66778709; called by muse, mutect2, varscan2
- TBC1D22B | c.745A>C p.I249L | Missense Mutation (SNP) | VAF 80/587 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV100996568; called by muse, mutect2, varscan2
- TBC1D31 | c.2870G>A p.R957K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99782174; called by muse, mutect2, varscan2
- TCP11L1 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.595); catalogued as rs1426442304, COSV57515489; called by muse, mutect2, varscan2
- TENM4 | c.5723A>G p.D1908G | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1201064079, COSV99569241; called by muse, mutect2, varscan2
- TFAP2A | c.125C>T p.T42M (on ENST00000482890; = p.T34M on NM_001032280.3) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs1231120267, COSV60234086; called by muse, mutect2, varscan2
- TGM6 | c.1988A>C p.Q663P | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); catalogued as COSV99171642; called by muse, mutect2, varscan2
- TIAM1 | c.2842G>T p.A948S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99731670; called by muse, varscan2
- TLE6 | c.459G>A p.W153* (on ENST00000246112 / NM_001143986.2; = p.W30* on NM_024760.3) | Nonsense Mutation (SNP) | VAF 43/101 reads (43%) | catalogued as COSV99857811; called by muse, mutect2, varscan2
- TMEM44 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs199697463, COSV99861460; called by muse, mutect2, varscan2
- TPTE2 | c.1524T>G p.I508M (on ENST00000400230 / NM_199254.2; = p.I431M on NM_130785.3) | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs780874714, COSV55027931; called by muse, mutect2, varscan2
- TRMT5 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV50781285; called by muse, mutect2, varscan2
- TSPAN18 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 89/259 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375081402; called by muse, mutect2, varscan2
- TTC29 | c.56G>C p.R19T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV100282949, COSV57275668; called by muse, mutect2, varscan2
- TTN | c.51924A>C p.K17308N (on ENST00000591111; = p.K9884N on NM_003319.4) | Missense Mutation (SNP) | VAF 43/99 reads (43%) | PolyPhen benign (0.173); catalogued as COSV100587893; called by muse, mutect2, varscan2
- TTN | c.51265G>T p.E17089* (on ENST00000591111; = p.E9665* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 37/76 reads (49%) | catalogued as COSV100587896; called by muse, mutect2, varscan2
- TTN | c.50208A>C p.E16736D (on ENST00000591111; = p.E9312D on NM_003319.4) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | PolyPhen benign (0.006); catalogued as COSV59915047; called by muse, mutect2, varscan2
- TTN | c.12620T>G p.V4207G (on ENST00000591111; = p.V4161G on NM_003319.4) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | catalogued as COSV100587899; called by muse, mutect2, varscan2
- UGP2 | c.843A>C p.E281D | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100451425, COSV61430143; called by muse, mutect2, varscan2
- UHRF1 | c.1451G>A p.R484Q (on ENST00000612630 / NM_001290050.1; = p.R497Q on NM_013282.4) | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99503222; called by muse, mutect2, varscan2
- UNC13C | c.1046C>A p.S349* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV52873149, COSV99509498; called by muse, mutect2, varscan2
- UNC45A | c.1948T>A p.C650S | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV101265630; called by muse, mutect2, varscan2
- USP25 | c.1919C>T p.S640F | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99582870; called by muse, mutect2, varscan2
- VIPR2 | c.745T>G p.W249G | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100056266; called by muse, mutect2, varscan2
- VPS13B | c.2396A>G p.Q799R | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV100660355; called by muse, mutect2, varscan2
- VTA1 | c.524T>C p.I175T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs753854014, COSV100859144; called by muse, mutect2, varscan2
- WDR44 | c.2673A>C p.E891D | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.21); PolyPhen benign (0.119); catalogued as COSV54163769; called by muse, mutect2, varscan2
- WFIKKN2 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs200820844, COSV100259677; called by muse, mutect2, varscan2
- XDH | c.3938A>C p.K1313T | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV101051865; called by muse, mutect2, varscan2
- ZFHX4 | c.1841A>G p.E614G | Missense Mutation (SNP) | VAF 70/123 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs547700879, COSV99254055; called by muse, mutect2, varscan2
- ZMYM6 | c.1497C>A p.C499* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as COSV100592944; called by muse, mutect2, varscan2
- ZNF236 | c.1727G>T p.R576L | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53482177, COSV99468380; called by muse, mutect2, varscan2
- ZNF548 | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs377304568; called by muse, mutect2, varscan2
- ZNF98 | c.367A>G p.R123G | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV63335342, COSV63340837; called by muse, mutect2, varscan2
- ZSCAN1 | c.63G>T p.E21D | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.535); catalogued as COSV99991209; called by muse, mutect2, varscan2
- ARID1A | c.3392_3395del p.Q1131Lfs*29 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- BIRC2 | c.29dup p.G12Rfs*8 | Frame Shift Ins (INS) | VAF 34/113 reads (30%) | called by mutect2, pindel, varscan2
- IGHM | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- PLPPR4 | c.1299_1332del p.I435Sfs*20 | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | called by mutect2, pindel
- TPTE | c.248A>C p.K83T (on ENST00000618007 / NM_199261.4; = p.K65T on NM_199259.4) | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- ABCC4 | c.1765T>C p.L589= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs1421554031, COSV100972146; called by muse, mutect2, varscan2
- ADGRG4 | c.5415T>G p.T1805= | Silent (SNP) | VAF 27/45 reads (60%) | catalogued as COSV99793984; called by muse, mutect2, varscan2
- ANK1 | c.5298C>T p.P1766= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as rs909120771, COSV99223396; called by muse, mutect2, varscan2
- ANKRD30A | c.2691G>A p.L897= (on ENST00000611781; = p.L841= on NM_052997.2) | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV100652535; called by muse, mutect2, varscan2
- APC | c.5067C>T p.T1689= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs1554086427, COSV99964165; ClinVar: likely benign; called by muse, mutect2, varscan2
- BPIFB3 | c.810G>T p.V270= | Silent (SNP) | VAF 33/140 reads (24%) | catalogued as COSV100972257; called by muse, mutect2, varscan2
- C11orf1 | c.42C>T p.F14= | Silent (SNP) | VAF 57/204 reads (28%) | catalogued as COSV99499364; called by muse, mutect2, varscan2
- CAMKK2 | c.156C>T p.F52= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs955854076, COSV100242493; called by muse, mutect2, varscan2
- CASS4 | c.1080T>C p.S360= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as COSV100824488; called by muse, mutect2, varscan2
- CFAP69 | c.1338A>T p.R446= | Silent (SNP) | VAF 32/129 reads (25%) | catalogued as COSV100289642; called by muse, mutect2, varscan2
- CLDN16 | c.627C>T p.A209= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs745542693, COSV99289875; called by muse, mutect2, varscan2
- CLPTM1 | c.1266C>T p.S422= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as COSV100493503; called by muse, mutect2, varscan2
- CNBD2 | c.273C>A p.I91= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV100839009, COSV100839113; called by muse, mutect2, varscan2
- COPB1 | c.229T>C p.L77= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV99999086; called by muse, mutect2, varscan2
- DMRTC2 | c.27C>T p.G9= | Silent (SNP) | VAF 57/206 reads (28%) | catalogued as COSV99523264; called by muse, mutect2, varscan2
- DTX3L | c.1764A>G p.K588= | Silent (SNP) | VAF 83/210 reads (40%) | catalogued as COSV99949776; called by muse, mutect2, varscan2
- FAT3 | c.3201T>C p.A1067= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV99959496; called by muse, mutect2, varscan2
- FCRL4 | c.588A>G p.K196= | Silent (SNP) | VAF 24/128 reads (19%) | catalogued as COSV99619061; called by muse, mutect2, varscan2
- FGF20 | c.571T>C p.L191= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as rs370810066; called by muse, mutect2, varscan2
- FHOD3 | c.2115G>A p.Q705= (on ENST00000359247 / NM_001281739.3; = p.Q722= on NM_025135.5) | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV99939560; called by muse, mutect2, varscan2
- FPGT | c.1062T>C p.L354= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV100906827; called by muse, mutect2, varscan2
- FUZ | c.204G>T p.T68= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV100570936, COSV58242824; called by muse, mutect2, varscan2
- GNA15 | c.513C>T p.T171= | Silent (SNP) | VAF 52/181 reads (29%) | catalogued as rs368743040, COSV99504941; called by muse, mutect2, varscan2
- GNLY | c.312C>T p.R104= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as rs1433493473, COSV99808820; called by muse, mutect2, varscan2
- GTPBP2 | c.1455A>G p.A485= | Silent (SNP) | VAF 88/1396 reads (6%) | catalogued as rs748492429, COSV100199782; called by muse, mutect2
- HCK | c.669G>A p.V223= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs772900757, COSV99393529; called by muse, mutect2, varscan2
- IGHA1 | c.456G>C p.L152= | Silent (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- IGHM | c.54G>A p.P18= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs569451306; called by muse, mutect2
- IGHV1-69 | c.285G>A p.T95= | Silent (SNP) | VAF 95/276 reads (34%) | catalogued as rs538853354; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1797T>A p.A599= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV100144318; called by muse, mutect2, varscan2
- KAT6A | c.2598C>T p.G866= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as COSV99704109; called by muse, mutect2, varscan2
- KDM5A | c.2175C>T p.L725= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs752225628, COSV101238518; called by muse, mutect2, varscan2
- KDR | c.825A>G p.R275= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV99816335; called by muse, varscan2
- LAMC1 | c.3525C>T p.N1175= | Silent (SNP) | VAF 51/289 reads (18%) | catalogued as COSV51186918; called by muse, mutect2, varscan2
- LENG9 | c.1375C>T p.L459= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as rs139044470, COSV56619039; called by muse, mutect2, varscan2
- MAGEA12 | c.744A>G p.Q248= | Silent (SNP) | VAF 76/105 reads (72%) | catalogued as rs1556833588, COSV100756767, COSV63294236; called by muse, mutect2, varscan2
- MMP2 | c.1164C>A p.G388= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV99527266; called by muse, mutect2, varscan2
- MROH9 | c.451A>C p.R151= | Silent (SNP) | VAF 47/224 reads (21%) | catalogued as COSV100882619; called by muse, mutect2, varscan2
- NPAS3 | c.2091C>T p.G697= (on ENST00000356141 / NM_001164749.2; = p.G665= on NM_022123.3) | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs1328116992, COSV60824353; called by muse, mutect2, varscan2
- NPHP3 | c.345C>T p.R115= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100446517; called by muse, mutect2, varscan2
- NRXN1 | c.255C>T p.R85= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV68009123; called by muse, mutect2, varscan2
- NUP42 | c.1252C>T p.L418= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99330803; called by muse, mutect2, varscan2
- OR13A1 | c.84C>T p.T28= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs767839203, COSV100981032, COSV65572255; called by muse, mutect2, varscan2
- P2RX5 | c.1017C>T p.L339= | Silent (SNP) | VAF 26/34 reads (76%) | catalogued as COSV56593608; called by muse, mutect2, varscan2
- PCDH17 | c.330C>T p.A110= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100931357; called by muse, mutect2, varscan2
- PDZRN4 | c.1522T>C p.L508= (on ENST00000402685 / NM_001164595.2; = p.L250= on NM_013377.4) | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs201709547, COSV100113210; called by muse, mutect2, varscan2
- PKD1L1 | c.3573G>A p.P1191= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs201948356, COSV99217862; called by muse, mutect2, varscan2
- PKD1L1 | c.3462G>A p.V1154= | Silent (SNP) | VAF 33/149 reads (22%) | catalogued as rs775126059, COSV99217863; called by muse, mutect2, varscan2
- PKP1 | c.1500C>T p.N500= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as rs776031745, COSV99824718; called by muse, mutect2, varscan2
- RFTN2 | c.1338G>A p.L446= | Silent (SNP) | VAF 43/125 reads (34%) | catalogued as COSV99695066; called by muse, mutect2, varscan2
- SCN5A | c.888C>T p.A296= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as rs774132896, COSV100345674; ClinVar: likely benign; called by muse, mutect2, varscan2
- SIGLEC7 | c.465C>T p.P155= | Silent (SNP) | VAF 80/228 reads (35%) | catalogued as rs186385053, COSV58316599, COSV99978314; called by muse, mutect2, varscan2
- SIRT3 | c.855C>T p.G285= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs562348241, COSV101236022; called by muse, mutect2, varscan2
- SKIDA1 | c.33G>A p.V11= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV101481222; called by muse, mutect2
- SLC9A5 | c.1587C>T p.Y529= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as COSV100236943; called by muse, mutect2, varscan2
- SMG5 | c.504G>A p.Q168= | Silent (SNP) | VAF 58/277 reads (21%) | catalogued as COSV62434360; called by muse, mutect2, varscan2
- SNX17 | c.336C>A p.V112= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1284830158, COSV99277109; called by muse, mutect2, varscan2
- SOAT2 | c.993C>T p.F331= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV100037312; called by muse, mutect2, varscan2
- SORBS3 | c.1650C>A p.R550= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV99530857; called by muse, mutect2, varscan2
- SOX17 | c.645C>T p.D215= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV52025479; called by muse, mutect2
- SPAG17 | c.207G>A p.S69= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs770924560, COSV100307377, COSV100309675; called by muse, mutect2, varscan2
- SPANXB1 | c.108T>C p.T36= | Silent (SNP) | VAF 41/110 reads (37%) | called by muse, mutect2, varscan2
- SPTA1 | c.381A>G p.E127= | Silent (SNP) | VAF 38/194 reads (20%) | catalogued as rs199927411, COSV100933971; called by muse, mutect2, varscan2
- STK32B | c.1230T>G p.R410= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV99283624; called by muse, mutect2, varscan2
- TECTA | c.5472T>G p.G1824= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV99878089; called by muse, mutect2, varscan2
- TP53I11 | c.21G>A p.P7= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs142855030; called by muse, varscan2
- TRAV18 | c.150T>G p.T50= | Silent (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- TRIM29 | c.1647G>A p.R549= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV59279988; called by muse, mutect2, varscan2
- TRIML2 | c.1014A>G p.K338= | Silent (SNP) | VAF 59/198 reads (30%) | catalogued as COSV58714561, COSV58718244, COSV58720356; called by muse, mutect2, varscan2
- ZNF273 | c.495A>G p.G165= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as rs754690907, COSV100139090; called by muse, mutect2, varscan2
- ATP11AUN | n.786G>A | RNA (SNP) | VAF 26/58 reads (45%) | catalogued as rs917606966; called by muse, mutect2, varscan2
- DENND10P1 | n.857C>T | RNA (SNP) | VAF 29/44 reads (66%) | catalogued as rs1406825863; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85590T>C | Intron (SNP) | VAF 20/47 reads (43%) | catalogued as rs377692062, COSV72284611; called by muse, mutect2, varscan2
- Unknown | chr21:16194613 C>T | IGR (SNP) | VAF 19/64 reads (30%) | catalogued as rs759309440; called by muse, mutect2, varscan2
